Gene-level copy-number profile of tumor specimen TCGA-25-1623-01A from TCGA case TCGA-25-1623, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 71.3 years (26,060 days).
Specimen TCGA-25-1623-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.fb6d2d72-8352-495b-96c7-69e45636ad78.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-25-1623-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dac024ca-3cdf-49bc-9687-c4a2608c329c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 2: 8,252; copy number 4: 28,853; copy number 5: 3,970; copy number 6: 12,329; copy number 7: 2,200; copy number 8: 2,506; copy number 9: 42; copy number 10: 839; copy number 11: 159; copy number 12: 59; copy number 13: 134; copy number 14: 139; copy number 15: 5; copy number 16: 89; copy number 17: 32; copy number 18: 3; copy number 20: 70; copy number 23: 58; copy number 45: 41; copy number 66: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-25-1623-01): tumor purity 0.38, ploidy 2.44, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:26,546,802–26,729,126, 3 genes (within-gene range 0–4): AC002331.1, LINC02195, AC009035.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,707 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,364,633–34,859,755, 58 genes, copy number 12 (within-gene range 4–12): BSDC1, GAPDHP20, AL356986.1, LRRC37A12P, RN7SL122P, AL033529.1, ZBTB8B, ZBTB8A, ZBTB8OS, Y_RNA, RBBP4, SYNC, AC114489.1, KIAA1522, YARS1, S100PBP, FNDC5, HPCA, TMEM54, AL031602.2, RNF19B, AL031602.1, AL355864.1, AL355864.2, AL020995.1, AK2, Metazoa_SRP, AZIN2, AL662907.1, TRIM62, AL662907.2, AL662907.3, ZNF362, AL513327.2, A3GALT2, AL513327.1, PHC2, MIR3605, RN7SKP16, PHC2-AS1, TLR12P, ZSCAN20, AC115285.1, CSMD2, HSPD1P14, HMGB4, CSMD2-AS1, RNA5SP42, C1orf94, AC115286.1, AC099565.1, MIR552, SMIM12, GJB5, GJB4, AL121988.1, GJB3, GJA4.
- chr1:48,497,263–52,090,716, 66 genes, copy number 11–23 (within-gene range 5–23) (broad region; genes not listed).
- chr1:53,441,268–54,742,657, 38 genes, copy number 13 (within-gene range 4–13): AL365445.1, DMRTB1, GLIS1, RNU7-95P, NDC1, AL049745.1, AL049745.2, YIPF1, DIO1, HSPB11, LRRC42, HNRNPA3P12, LDLRAD1, TMEM59, AL353898.3, TCEANC2, MIR4781, AL353898.1, AL353898.2, AL357673.1, CDCP2, AL357673.2, CYB5RL, MRPL37, SSBP3, SSBP3-AS1, AL161644.1, AL035415.1, AC099796.2, LINC02784, AC099796.1, HNRNPA1P63, ACOT11, FAM151A, AL590093.1, MROH7, MROH7-TTC4, TTC4.
- chr1:67,832,303–68,202,987, 4 genes, copy number 12–18 (within-gene range 4–18): GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3.
- chr3:70,808,350–78,525,485, 102 genes, copy number 10 (broad region; genes not listed).
- chr3:78,758,974–78,938,292, 2 genes, copy number 10: AC055731.1, RN7SL751P.
- chr3:84,638,405–94,131,832, 59 genes, copy number 10: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19, ABBA01000933.1, ABBA01000935.2, RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2.
- chr5:21,323,873–35,230,487, 176 genes, copy number 13–16 (within-gene range 6–16) (broad region; genes not listed).
- chr6:167,607–2,245,605, 33 genes, copy number 10–17 (within-gene range 6–17): AL035696.2, AL035696.3, AL035696.4, AL035696.1, AL365272.1, DUSP22, IRF4, AL512308.1, EXOC2, AL031770.1, HUS1B, AL357054.1, AL357054.2, AL357054.4, AL357054.5, AL357054.3, AL392183.1, AL356130.1, LINC01622, AL033381.2, AL033381.1, AL033381.3, FOXQ1, LINC01394, AL034346.1, FOXF2, MIR6720, RN7SL352P, AL512329.1, AL512329.2, FOXCUT, FOXC1, GMDS.
- chr8:123,768,439–128,564,679, 83 genes, copy number 9–45 (within-gene range 7–45) (broad region; genes not listed).
- chr11:22,261,209–22,813,055, 9 genes, copy number 10 (within-gene range 6–10): AC107886.1, AC104009.1, SLC17A6, AC040936.1, LINC01495, AC055878.1, FANCF, GAS2, RNA5SP338.
- chr11:96,590,317–103,092,194, 66 genes, copy number 11–66 (within-gene range 4–66) (broad region; genes not listed).
- chr18:20,946,906–25,352,190, 98 genes, copy number 14 (broad region; genes not listed).
- chr19:20,535,825–23,445,189, 136 genes, copy number 11 (broad region; genes not listed).
- chr19:31,797,666–39,943,680, 376 genes, copy number 10–20 (within-gene range 6–20) (broad region; genes not listed).
- chr20:39,655,325–58,451,101, 401 genes, copy number 10 (within-gene range 6–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
